Somatic mutation profile of tumor specimen C3L-02559-01 (aliquot CPT0128290006) from CPTAC case C3L-02559, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 65.7 years (23,982 days).
Specimen C3L-02559-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2c9b51f-fd6c-4021-87fd-d3a599aa133c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02559-31 (Blood Derived Normal), aliquot CPT0129460002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbeed18a-da5f-4447-a874-07f0de194adb

The open-access MAF lists 60 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 15, Intron 4, 5'UTR 3, Frame Shift Del 3, Nonsense Mutation 2, 5'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.1858del p.R620Gfs*23 | Frame Shift Del (DEL) | VAF 32/218 reads (15%) | catalogued as COSV57291705; called by mutect2, varscan2
- AMIGO2 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs765792219; called by muse, mutect2, varscan2
- BCHE | c.111G>C p.K37N | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1385639557, COSV52254088; called by muse, mutect2
- COL18A1 | c.1400C>T p.P467L (on ENST00000359759 / NM_130444.3; = p.P232L on NM_030582.4) | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs529544471, COSV100700574; called by muse, mutect2, varscan2
- DCAF12L1 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1176083541, COSV64421966, COSV64422026; called by muse, mutect2, varscan2
- KLF4 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65928639; called by muse, mutect2
- KRT4 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 83/507 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs377329227, COSV53409461; ClinVar: benign; called by muse, mutect2, varscan2
- OPLAH | c.2510C>T p.P837L | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781894813; called by muse, mutect2, varscan2
- PDGFD | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs760046138, COSV56395031; called by muse, mutect2, varscan2
- PRRC2B | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV61937640; called by muse, mutect2, varscan2
- ROBO1 | c.4357G>A p.A1453T | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs370200985; called by muse, mutect2, varscan2
- STIL | c.254C>A p.T85K | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV54554666; called by muse, mutect2
- SZT2 | c.2371C>T p.R791C | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746376950, COSV100987112; called by muse, mutect2
- TSHZ2 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as rs138844500, COSV61592313; called by muse, mutect2, varscan2
- TSPAN14 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs765290404, COSV99627760; called by muse, mutect2, varscan2
- ZNF568 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs777205945; called by muse, mutect2, varscan2
- ABCC2 | c.3600G>C p.W1200C | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); called by muse, mutect2
- AC055839.2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARL8A | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- BRCA1 | c.3139G>T p.V1047L | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- ELMO1 | c.804G>T p.Q268H | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2
- KDM4D | c.548G>C p.G183A | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NSMCE4A | c.1084-7C>G | Splice Region (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- OR11H12 | c.767G>T p.C256F | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- PAICS | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | PolyPhen benign (0.141); called by muse, varscan2
- PSMG1 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.424); called by muse, mutect2
- PTPN2 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 31/215 reads (14%) | called by muse, mutect2, varscan2
- SETD2 | c.7614_7615del p.H2538Qfs*7 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | called by pindel, varscan2
- SETDB1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 36/176 reads (20%) | called by muse, mutect2, varscan2
- SLC25A13 | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A16 | c.2158A>T p.I720F | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- TENM4 | c.6092G>A p.S2031N | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2
- XIRP2 | c.7423G>A p.E2475K (on ENST00000628543; = p.E2650K on NM_152381.6) | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF222 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF267 | c.874_875del p.E292Kfs*4 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- ZNF502 | c.774G>C p.Q258H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ACP3 | c.924T>A p.P308= | Silent (SNP) | VAF 39/232 reads (17%) | called by muse, mutect2, varscan2
- CACNA1F | c.2721C>T p.F907= | Silent (SNP) | VAF 20/384 reads (5%) | catalogued as COSV59907457, COSV59907468; called by muse, mutect2
- COX18 | c.549C>T p.F183= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- CYP4F8 | c.318C>T p.I106= | Silent (SNP) | VAF 24/410 reads (6%) | catalogued as rs375063511, COSV100358293; called by muse, mutect2
- DIPK1B | c.828C>A p.I276= | Silent (SNP) | VAF 36/246 reads (15%) | called by muse, mutect2, varscan2
- FAM160B2 | c.174G>A p.Q58= | Silent (SNP) | VAF 17/176 reads (10%) | called by muse, mutect2, varscan2
- FCGBP | c.6825G>A p.P2275= | Silent (SNP) | VAF 34/1320 reads (3%) | catalogued as rs1465074897; called by muse, mutect2
- KCNS2 | c.144C>G p.L48= | Silent (SNP) | VAF 28/245 reads (11%) | called by muse, mutect2, varscan2
- KLF3 | c.459C>T p.V153= | Silent (SNP) | VAF 36/407 reads (9%) | catalogued as COSV54710813; called by muse, mutect2
- MYO9B | c.1566C>T p.F522= | Silent (SNP) | VAF 29/167 reads (17%) | catalogued as rs759342261, COSV68278683; called by muse, mutect2, varscan2
- NOTCH1 | c.2943G>A p.E981= | Silent (SNP) | VAF 28/516 reads (5%) | called by muse, mutect2
- PDGFA | c.357C>T p.I119= | Silent (SNP) | VAF 20/334 reads (6%) | called by muse, mutect2
- RNF43 | c.132G>A p.Q44= | Silent (SNP) | VAF 33/464 reads (7%) | catalogued as COSV100090176; called by muse, mutect2
- TRADD | c.414C>T p.C138= | Silent (SNP) | VAF 43/518 reads (8%) | called by muse, mutect2
- ZNF704 | c.1134C>T p.P378= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs759626842; called by muse, mutect2, varscan2
- ACSM2B | c.895-1332C>T | Intron (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2
- AP2A2 | c.*823C>T | 3'UTR (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- CSTA | c.168+16C>A | Intron (SNP) | VAF 3/42 reads (7%) | catalogued as rs928802066; called by muse, mutect2
- LHX2 | chr9:124007932 C>T | 5'Flank (SNP) | VAF 50/261 reads (19%) | called by muse, mutect2, varscan2
- RAP1GAP | c.-148-1834G>T | Intron (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- S100A11 | c.-14C>T | 5'UTR (SNP) | VAF 16/142 reads (11%) | catalogued as COSV99643276; called by muse, varscan2
- SMPD1 | c.-40G>A | 5'UTR (SNP) | VAF 54/246 reads (22%) | catalogued as rs1331708749, COSV100193080; called by muse, mutect2, varscan2
- TMEM135 | c.-100C>G | 5'UTR (SNP) | VAF 12/116 reads (10%) | catalogued as rs950019777; called by muse, mutect2
- ZNF195 | c.226+4126C>T | Intron (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
